Gene-level copy-number profile of tumor specimen C3L-01672-01 from CPTAC case C3L-01672, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIA; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.6 years (19,576 days).
Specimen C3L-01672-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 566e4437-8ee0-43ef-b32b-3b5ebac2d09e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01672-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/ea6c959f-d7c2-4236-ad90-16a706ef1d6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 386; copy number 2: 55,512; copy number 3: 102; copy number 5: 2,395; copy number 9: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,401 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–12,177,550, 297 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:12,194,467–145,066,685, 2,104 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
